Somatic mutation profile of tumor specimen C3N-03619-02 (aliquot CPT0195860009) from CPTAC case C3N-03619, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 59.6 years (21,757 days).
Specimen C3N-03619-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 804d3fd2-5022-4870-b918-252c41229b4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03619-71 (Blood Derived Normal), aliquot CPT0195970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed2e066-c832-43b4-af17-8b8957027f91

The open-access MAF lists 120 somatic variants for this specimen: 79 protein-altering or splice-affecting, 20 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 20, Intron 10, In Frame Del 3, RNA 3, Nonsense Mutation 3, 3'UTR 3, 5'UTR 2, Splice Site 2, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 171/518 reads (33%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALK | c.2431G>T p.V811L | Missense Mutation (SNP) | VAF 220/590 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as COSV101202750, COSV66560705; called by muse, mutect2, varscan2
- C1S | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 89/783 reads (11%) | catalogued as rs781856506, CM016095; called by muse, mutect2, varscan2
- CA9 | c.443C>G p.P148R | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.635); catalogued as COSV100999807; called by muse, mutect2, varscan2
- EZHIP | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100539997; called by muse, mutect2, varscan2
- GIGYF1 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 68/949 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as rs759049480; called by muse, mutect2
- KMT2C | c.7930A>G p.M2644V | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs376073836; called by muse, mutect2
- MAMDC2 | c.1919T>C p.F640S | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65859198; called by muse, mutect2, varscan2
- MLLT11 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 193/777 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV64462138; called by muse, mutect2, varscan2
- NXPE4 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV64944156; called by muse, mutect2, varscan2
- OAS3 | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 114/859 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201242016; called by muse, mutect2, varscan2
- OR51A4 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 34/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745475659; called by muse, mutect2
- OR52N1 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57692865; called by muse, mutect2, varscan2
- OR5D14 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1432595559, COSV59455695, COSV59458364; called by muse, mutect2, varscan2
- OR5F1 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.202); catalogued as COSV53545243; called by muse, mutect2, varscan2
- PCDHGA12 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as rs79883194; called by muse, mutect2, varscan2
- PLD4 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs1420690728; called by muse, mutect2, varscan2
- PRDM11 | c.578_580del p.F193del (on ENST00000530656 / NM_001359633.1; = p.F159del on NM_001256695.1) | In Frame Del (DEL) | VAF 28/164 reads (17%) | catalogued as rs1565299323; called by pindel, varscan2
- SH2D4B | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 35/539 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as rs1170040142; called by muse, mutect2
- SLC38A11 | c.500C>T p.A167V (on ENST00000409149 / NM_001351539.1; = p.A145V on NM_173512.2) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764538386; called by muse, mutect2, varscan2
- SPSB4 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779337757, COSV60144591; called by muse, mutect2, varscan2
- SSC5D | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); catalogued as rs770196004; called by muse, mutect2, varscan2
- STAG3 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 107/1470 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149765159; called by muse, mutect2
- THPO | c.1136C>T p.S379F (on ENST00000649095 / NM_001290003.1; = p.S239F on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/448 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.03); catalogued as COSV99201252; called by muse, mutect2, varscan2
- TUFT1 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV61949651; called by muse, mutect2, varscan2
- ZC3H14 | c.37-3_37-2del p.X13_splice | Splice Site (DEL) | VAF 164/677 reads (24%) | catalogued as rs1479153950; called by mutect2, pindel, varscan2
- ABCC4 | c.3476T>C p.I1159T | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- ADAMTS18 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 317/1032 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- AFF1 | c.254A>C p.N85T | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ATR | c.4418G>A p.G1473E | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BPIFC | c.892_898del p.G298Sfs*40 | Frame Shift Del (DEL) | VAF 51/156 reads (33%) | called by pindel, varscan2
- BRIP1 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAMK2D | c.1064A>T p.E355V | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CCDC18 | c.3834A>C p.Q1278H (on ENST00000343253 / NM_001306076.1; = p.Q1279H on NM_206886.4) | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- CENATAC | c.343A>T p.M115L | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHD1L | c.1880G>C p.G627A | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNASE1L1 | c.131T>A p.V44D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK4 | c.4991C>A p.S1664Y | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DSTYK | c.2124_2135del p.E708_V711del | In Frame Del (DEL) | VAF 32/312 reads (10%) | called by mutect2, pindel
- EGLN1 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 57/458 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GLRX5 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- GSTZ1 | c.421+8C>T | Splice Region (SNP) | VAF 110/445 reads (25%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KANSL3 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 65/573 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KCNV1 | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 53/477 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP13-1 | c.463A>T p.R155W | Missense Mutation (SNP) | VAF 50/383 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LETM2 | c.443C>A p.A148D (on ENST00000379957 / NM_001286819.2; = p.A101D on NM_144652.3) | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- LNX1 | c.1361G>C p.R454T (on ENST00000263925 / NM_001126328.3; = p.R358T on NM_032622.2) | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.324); called by muse, varscan2
- MAMDC4 | c.1594T>A p.F532I | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MTRES1 | c.482dup p.D161Efs*7 | Frame Shift Ins (INS) | VAF 30/184 reads (16%) | called by mutect2, pindel, varscan2
- NBEA | c.5832T>A p.C1944* | Nonsense Mutation (SNP) | VAF 54/357 reads (15%) | called by muse, mutect2, varscan2
- NEB | c.15072G>T p.L5024F | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP50 | c.424T>A p.S142T | Missense Mutation (SNP) | VAF 84/477 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR8I2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OR8I2 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PCDHB14 | c.1163A>G p.N388S | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2
- PCDHGA9 | c.1700T>C p.L567P | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PKD1 | c.1236C>G p.I412M | Missense Mutation (SNP) | VAF 130/1022 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- POP1 | c.1710+1G>T p.X570_splice | Splice Site (SNP) | VAF 86/435 reads (20%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRM2 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 117/849 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RC3H1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RC3H1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- RERE | c.2020A>T p.I674F | Missense Mutation (SNP) | VAF 90/700 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RTN4 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RUSC1 | c.1591_1593del p.L531del (on ENST00000368352 / NM_001105203.2; = p.L62del on NM_014328.4 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 62/600 reads (10%) | called by mutect2, pindel
- RYR1 | c.4813A>T p.S1605C | Missense Mutation (SNP) | VAF 160/1219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHLD2 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SIRPB1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 48/550 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.052); called by muse, mutect2
- SOX4 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 28/830 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBC1D24 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 181/1464 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TSPAN10 | c.203G>T p.C68F (on ENST00000574882 / NM_001290212.1; = p.C30F on NM_031945.4) | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- UBE4B | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.098); called by muse, mutect2
- UTRN | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDSUB1 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ZKSCAN1 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF43 | c.1367G>T p.C456F | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF652 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 55/442 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.1428G>C p.K476N | Missense Mutation (SNP) | VAF 136/648 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTL8 | c.96C>T p.I32= | Silent (SNP) | VAF 129/628 reads (21%) | catalogued as rs774216868, COSV64861788; called by muse, mutect2, varscan2
- CSMD1 | c.8868C>T p.S2956= (on ENST00000520002; = p.S2955= on NM_033225.6) | Silent (SNP) | VAF 56/392 reads (14%) | catalogued as COSV100145502, COSV59377178; called by muse, mutect2, varscan2
- CYP21A2 | c.366G>A p.K122= | Silent (SNP) | VAF 135/1330 reads (10%) | catalogued as rs758096687; called by muse, varscan2
- ELMOD1 | c.201G>A p.Q67= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- ELOVL3 | c.585C>A p.P195= | Silent (SNP) | VAF 88/650 reads (14%) | called by muse, mutect2, varscan2
- EXOC1L | c.297G>A p.L99= | Silent (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- GSTM5 | c.345C>T p.C115= | Silent (SNP) | VAF 32/268 reads (12%) | called by muse, mutect2, varscan2
- H1-4 | c.222G>A p.E74= | Silent (SNP) | VAF 61/488 reads (13%) | catalogued as rs577624174; called by muse, mutect2, varscan2
- HECTD4 | c.4341C>T p.F1447= | Silent (SNP) | VAF 39/320 reads (12%) | catalogued as rs1242754555; called by muse, mutect2, varscan2
- HTT | c.7794G>A p.L2598= | Silent (SNP) | VAF 44/397 reads (11%) | called by muse, mutect2, varscan2
- KDM5B | c.3732T>A p.V1244= | Silent (SNP) | VAF 71/645 reads (11%) | called by muse, mutect2, varscan2
- MIOS | c.1521C>T p.D507= | Silent (SNP) | VAF 26/294 reads (9%) | catalogued as rs760095430; called by muse, mutect2
- NUGGC | c.63A>G p.K21= | Silent (SNP) | VAF 58/183 reads (32%) | called by muse, mutect2, varscan2
- OR5T1 | c.534G>A p.L178= | Silent (SNP) | VAF 37/362 reads (10%) | catalogued as rs772889636; called by muse, varscan2
- RASGRF1 | c.591C>T p.N197= | Silent (SNP) | VAF 77/329 reads (23%) | catalogued as rs763745429; called by muse, mutect2, varscan2
- RB1 | c.2499A>G p.V833= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs547398431; called by muse, mutect2, varscan2
- RXFP3 | c.315G>A p.L105= | Silent (SNP) | VAF 45/451 reads (10%) | called by muse, mutect2
- UBR1 | c.3045A>G p.E1015= | Silent (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- ZNF233 | c.1590C>T p.H530= | Silent (SNP) | VAF 47/317 reads (15%) | catalogued as rs1241494362; called by muse, mutect2, varscan2
- ZNF33A | c.2271C>T p.F757= (on ENST00000458705 / NM_006974.3; = p.F758= on NM_006954.2) | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV56723709; called by muse, mutect2
- ACSF3 | c.*874G>A | 3'UTR (SNP) | VAF 119/1026 reads (12%) | called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904763 G>A | 5'Flank (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.489G>C | RNA (SNP) | VAF 14/102 reads (14%) | catalogued as rs576380789; called by muse, mutect2
- BCL2L11 | c.498+3668dup | Intron (INS) | VAF 20/206 reads (10%) | called by mutect2, pindel
- CD99 | c.67+455C>A | Intron (SNP) | VAF 158/993 reads (16%) | called by muse, mutect2, varscan2
- CDT1 | c.*13dup | 3'UTR (INS) | VAF 66/342 reads (19%) | called by mutect2, pindel
- CERS5 | c.872+104T>C | Intron (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- DCHS2 | n.4456C>A | RNA (SNP) | VAF 19/126 reads (15%) | catalogued as COSV61776880; called by muse, mutect2, varscan2
- DZANK1 | chr20:18380883 G>T | 3'Flank (SNP) | VAF 31/236 reads (13%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-1535G>A | Intron (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- JAM2 | c.865-381C>T | Intron (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- NPIPB10P | n.1315A>G | RNA (SNP) | VAF 48/1058 reads (5%) | called by muse, mutect2
- SCFD2 | c.1562-35292A>G | Intron (SNP) | VAF 56/538 reads (10%) | called by muse, mutect2
- SDHAF2 | c.37-807G>T | Intron (SNP) | VAF 23/220 reads (10%) | called by muse, mutect2, varscan2
- STON1 | c.-69C>T | 5'UTR (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- SYNE2 | c.18038+741T>G | Intron (SNP) | VAF 46/620 reads (7%) | called by muse, mutect2
- TAOK2 | chr16:29991387 C>T | 3'Flank (SNP) | VAF 10/76 reads (13%) | catalogued as rs748096970; called by muse, mutect2
- TROAP | c.2099-34C>G | Intron (SNP) | VAF 55/303 reads (18%) | called by muse, mutect2, varscan2
- VPS13B | c.4820+15717C>G | Intron (SNP) | VAF 33/505 reads (7%) | catalogued as rs1384140695; called by muse, mutect2
- ZNF528 | c.-105T>C | 5'UTR (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- ZNF778 | c.*5019A>G | 3'UTR (SNP) | VAF 67/634 reads (11%) | catalogued as rs1348216953; called by muse, varscan2
